Gene-level copy-number profile of tumor specimen ALCH-AEZL-TTP1-A from ALCHEMIST case ALCH-AEZL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.9 years (18,605 days).
Specimen ALCH-AEZL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e5e14f0d-0f99-48d9-962a-b5ad03ee70b0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEZL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/de74cf0b-e9a6-44aa-8271-c6ee698c2020

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 562; copy number 1: 24,079; copy number 2: 32,072; copy number 3: 2,015; copy number 4: 173; copy number 5: 3; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr4:9,422,313–9,429,702, 1 gene: DEFB130D.
- chr4:69,306,469–69,307,173, 1 gene (within-gene range 0–2): AC114786.3.
- chr5:172,662,165–172,662,263, 1 gene (within-gene range 0–1): MIR5003.
- chr6:170,254,334–170,276,762, 2 genes (within-gene range 0–1): AL109910.1, AL109910.2.
- chr7:2,257,515–2,257,577, 1 gene (within-gene range 0–1): MIR6836.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr8:100,158,868–100,165,478, 2 genes (within-gene range 0–2): Y_RNA, AC025647.1.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–1): EMX2.
- chr11:65,615,773–65,637,439, 2 genes (within-gene range 0–1): PCNX3, MIR4690.
- chr11:65,649,192–65,649,253, 1 gene (within-gene range 0–1): MIR4489.
- chr16:1,431,078–1,444,556, 3 genes: PERCC1, CCDC154, AL032819.2.
- chr16:88,079,161–88,087,383, 1 gene (within-gene range 0–1): AC134312.4.
- chr16:88,088,041–88,100,985, 1 gene (within-gene range 0–1): AC134312.1.
- chr17:81,927,829–81,947,601, 5 genes: MAFG-DT, PYCR1, AC145207.4, MYADML2, AC145207.1.
- chr19:956,485–958,149, 1 gene (within-gene range 0–1): AC005391.1.
- chr19:5,782,960–5,784,746, 1 gene (within-gene range 0–1): PRR22.
- chr19:11,420,604–11,450,968, 2 genes: CCDC151, PRKCSH.
- chr19:35,014,961–35,040,449, 2 genes (within-gene range 0–4): AC020907.4, SCN1B.
- chr19:39,328,353–39,342,372, 2 genes: GMFG, AC011445.1.
- chr19:48,968,130–48,993,310, 1 gene: GYS1.
- chr20:62,427,827–62,478,594, 3 genes: AL121832.1, GATA5, AL499627.2.
- chr22:19,031,564–19,122,454, 6 genes (within-gene range 0–1): CA15P1, DGCR2, Y_RNA, DGCR11, AC004461.1, AC004461.2.
- chr22:23,359,603–23,402,726, 3 genes: CES5AP1, ZDHHC8P1, AP000344.2.
- chr22:34,756,676–35,002,862, 1 gene: LINC02885.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,449,689–1,470,163, 1 gene, copy number 6: ATAD3C.
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.
- chr11:1,683,269–1,689,056, 2 genes, copy number 5: FAM99B, LINC02708.
- chr17:4,937,130–4,949,061, 3 genes, copy number 6 (within-gene range 2–6): SLC25A11, RNF167, PFN1.

Autosomal genes at a single copy (total copy number 1): 21,766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
